Somatic mutation profile of tumor specimen 4b68d71e-48b4-45ba-a041-9d6aa0 (aliquot 4b68d71e-48b4-45ba-a041-9d6aa0_D8_1) from CPTAC case 11CO042, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 4b68d71e-48b4-45ba-a041-9d6aa0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60e6e27b-09b9-4fac-90c3-972fa74b4009.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 163f4ce9-bec0-48bc-9899-033cb7 (Blood Derived Normal), aliquot 163f4ce9-bec0-48bc-9899-033cb7_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/621b83bf-df15-4bcc-8cc0-2a041d90acd8

The open-access MAF lists 179 somatic variants for this specimen: 124 protein-altering or splice-affecting, 34 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 34, Intron 12, Nonsense Mutation 9, Frame Shift Ins 4, RNA 4, 3'UTR 2, 5'UTR 2, Frame Shift Del 2, Splice Site 2, Splice Region 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RASA1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 34/72 reads (47%) | catalogued as rs137853218, CM081410, COSV57192495; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 106/254 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD31 | c.4263dup p.Q1422Tfs*12 | Frame Shift Ins (INS) | VAF 14/70 reads (20%) | catalogued as rs530301594; called by mutect2, varscan2
- ARHGAP19 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755467381, COSV57395116; called by muse, mutect2, varscan2
- ARID1A | c.1653C>A p.Y551* | Nonsense Mutation (SNP) | VAF 111/414 reads (27%) | catalogued as COSV61379405; called by muse, mutect2, varscan2
- ARL8B | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56579093; called by muse, mutect2, varscan2
- BCR | c.2585G>A p.R862Q | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs764693798; called by muse, mutect2, varscan2
- CD163 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100775675; called by muse, mutect2, varscan2
- CFAP54 | c.4922G>A p.R1641Q | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs141973450; called by muse, mutect2, varscan2
- CUBN | c.18A>T p.L6F | Missense Mutation (SNP) | VAF 83/332 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as rs567627753; called by muse, mutect2, varscan2
- DNAH2 | c.11041C>T p.R3681C | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs761347327, COSV66717215; called by muse, mutect2, varscan2
- EPHA5 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99894947; called by muse, mutect2, varscan2
- ESAM | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs766107198; called by muse, mutect2, varscan2
- ESPNL | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 107/314 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs775173460; called by muse, mutect2, varscan2
- EVA1A | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs370520675, COSV52059535; called by muse, mutect2, varscan2
- GDF11 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57689315; called by muse, mutect2, varscan2
- GNPAT | c.1658C>T p.T553M | Missense Mutation (SNP) | VAF 101/417 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs751812397; called by muse, mutect2, varscan2
- GPR158 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 70/257 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1238554003; called by muse, mutect2, varscan2
- GPR179 | c.2681G>A p.R894Q (on ENST00000621958; = p.R893Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.045); catalogued as rs567907035; called by muse, mutect2, varscan2
- GRID2IP | c.3399G>A p.S1133= | Splice Region (SNP) | VAF 90/348 reads (26%) | catalogued as rs1426354744; called by muse, mutect2, varscan2
- HID1 | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780665652, COSV60913186; called by muse, mutect2, varscan2
- HMCN1 | c.4189G>T p.D1397Y | Missense Mutation (SNP) | VAF 103/415 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54898621; called by muse, mutect2, varscan2
- ISYNA1 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 85/271 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs200357380, COSV99525982; called by muse, mutect2, varscan2
- JAKMIP1 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 105/386 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51540433; called by muse, mutect2, varscan2
- KCNQ3 | c.2513C>T p.T838M | Missense Mutation (SNP) | VAF 167/1148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs145883169; called by muse, mutect2, varscan2
- KLHL5 | c.628dup p.M210Nfs*8 | Frame Shift Ins (INS) | VAF 13/41 reads (32%) | catalogued as rs757382348; called by mutect2, varscan2
- LIG1 | c.1695C>G p.C565W | Missense Mutation (SNP) | VAF 77/286 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54393614, COSV99618858; called by muse, mutect2, varscan2
- LONP2 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs373609168; called by muse, mutect2, varscan2
- MAP7D2 | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.7); catalogued as rs748236132; called by muse, mutect2
- MCHR1 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 92/408 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs769748464; called by muse, mutect2, varscan2
- MGAT4C | c.1174dup p.I392Nfs*2 | Frame Shift Ins (INS) | VAF 44/240 reads (18%) | catalogued as rs746398787; called by mutect2, varscan2
- MYCBP2 | c.2428G>A p.G810R (on ENST00000357337; = p.G848R on NM_015057.5) | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs768713448; called by muse, mutect2, varscan2
- NAALAD2 | c.196T>A p.S66T | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs767329492; called by muse, mutect2, varscan2
- NADK2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201353448; called by muse, mutect2, varscan2
- NPAP1 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as rs753827965; called by muse, mutect2, varscan2
- NRCAM | c.106+1G>A p.X36_splice | Splice Site (SNP) | VAF 24/126 reads (19%) | catalogued as rs1439940108, COSV100695342; called by muse, mutect2, varscan2
- OBSCN | c.17572G>A p.A5858T | Missense Mutation (SNP) | VAF 82/278 reads (29%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.542); catalogued as rs185248109; called by muse, mutect2
- OLFM2 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427896763; called by muse, mutect2, varscan2
- PCDHB12 | c.1591G>A p.V531M | Missense Mutation (SNP) | VAF 120/1416 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs139448614, COSV99507114; called by muse, mutect2
- PML | c.2498C>T p.T833M | Missense Mutation (SNP) | VAF 121/344 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs746137264; called by muse, mutect2, varscan2
- PPRC1 | c.4151G>A p.R1384Q | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs777024793, COSV53384480; called by muse, mutect2, varscan2
- PRIMA1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 99/394 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.579); catalogued as rs1356463267; called by muse, mutect2, varscan2
- PRKDC | c.4622C>T p.A1541V | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201417758; called by muse, mutect2, varscan2
- RAB6B | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 106/421 reads (25%) | catalogued as COSV53312093; called by muse, mutect2, varscan2
- RPGRIP1L | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 136/370 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as rs781713688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SART1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs769498116; called by muse, mutect2, varscan2
- SCN10A | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs778169470, COSV71862286; called by muse, mutect2, varscan2
- SH2D5 | c.722G>A p.R241H (on ENST00000444387 / NM_001103161.2; = p.R157H on NM_001103160.2) | Missense Mutation (SNP) | VAF 85/319 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs766370454; called by muse, mutect2, varscan2
- SLC2A3 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.941); catalogued as rs777935518; called by muse, mutect2, varscan2
- SPINK14 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100810988, COSV63659196; called by muse, mutect2
- STXBP6 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs754315802, COSV60598050; called by muse, mutect2, varscan2
- TNFSF11 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 114/307 reads (37%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.099); catalogued as rs749110346; called by muse, mutect2, varscan2
- TTN | c.56053G>A p.A18685T (on ENST00000591111; = p.A11261T on NM_003319.4) | Missense Mutation (SNP) | VAF 26/242 reads (11%) | PolyPhen benign (0); catalogued as rs370995867; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBG1 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as rs768185824; called by muse, mutect2, varscan2
- ZCCHC12 | c.640A>G p.R214G | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.223); catalogued as rs17853670; called by muse, mutect2
- ZNF143 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV55179142; called by muse, mutect2, varscan2
- ZNF451 | c.2756G>T p.G919V (on ENST00000370706 / NM_001031623.3; = p.G871V on NM_015555.2) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62598256; called by muse, mutect2
- ZNF451 | c.2758A>T p.N920Y (on ENST00000370706 / NM_001031623.3; = p.N872Y on NM_015555.2) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV62598875; called by muse, mutect2
- ZNF687 | c.3343C>T p.R1115W | Missense Mutation (SNP) | VAF 73/241 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1161392217, COSV55017821; called by muse, mutect2, varscan2
- ABCB1 | c.118T>C p.F40L | Missense Mutation (SNP) | VAF 85/241 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP9 | c.3380A>C p.H1127P | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ASB10 | c.496G>T p.V166L (on ENST00000420175 / NM_001142459.2; = p.V151L on NM_080871.4) | Missense Mutation (SNP) | VAF 66/358 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP8B4 | c.1909G>T p.E637* | Nonsense Mutation (SNP) | VAF 42/115 reads (37%) | called by muse, mutect2, varscan2
- BRD9 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- CACNA1B | c.3965G>T p.C1322F | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCR6 | c.354C>A p.C118* | Nonsense Mutation (SNP) | VAF 47/179 reads (26%) | called by muse, mutect2, varscan2
- CDX2 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CFAP221 | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by mutect2, varscan2
- CFAP58 | c.1951G>T p.D651Y | Missense Mutation (SNP) | VAF 29/435 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CNKSR2 | c.960T>C p.P320= | Splice Region (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- CPLANE1 | c.8746G>T p.A2916S | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CZIB | c.102dup p.N35Qfs*4 | Frame Shift Ins (INS) | VAF 49/221 reads (22%) | called by mutect2, pindel, varscan2
- DARS2 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ENPP2 | c.623C>G p.T208S | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.031); called by muse, mutect2
- EPHB4 | c.800A>G p.K267R | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM120C | c.119A>G p.H40R | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- FAT3 | c.5610C>A p.N1870K | Missense Mutation (SNP) | VAF 124/491 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- FRYL | c.5965G>A p.D1989N | Missense Mutation (SNP) | VAF 100/356 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- FSIP2 | c.8452T>A p.F2818I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAD2 | c.1097C>A p.A366D | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNAI3 | c.258_259del p.R86Sfs*8 | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | called by pindel, varscan2
- GNAO1 | c.225C>A p.S75R | Missense Mutation (SNP) | VAF 52/308 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HGSNAT | c.1258C>T p.L420F | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- IL16 | c.2729C>A p.A910E (on ENST00000302987 / NM_172217.5; = p.A209E on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- IRX1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ITGAM | c.3346G>A p.G1116R (on ENST00000648685 / NM_001145808.2; = p.G1115R on NM_000632.4) | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRBOX1 | c.237G>C p.Q79H | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- LMTK2 | c.1315_1317del p.S439del | In Frame Del (DEL) | VAF 26/182 reads (14%) | called by pindel, varscan2
- LRRK1 | c.2846T>G p.I949S | Missense Mutation (SNP) | VAF 69/204 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MCF2L2 | c.878+2T>C p.X293_splice | Splice Site (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- MMUT | c.1580A>G p.Q527R | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- MTERF1 | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MYH10 | c.5146G>A p.E1716K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- NKX1-1 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- NOTCH2 | c.2035T>C p.C679R | Missense Mutation (SNP) | VAF 133/525 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NUDT4 | c.310T>A p.L104I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR51B2 | c.33G>T p.L11F | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PCDH15 | c.2188G>T p.E730* | Nonsense Mutation (SNP) | VAF 22/127 reads (17%) | called by muse, mutect2, varscan2
- PLEKHA4 | c.1316A>G p.H439R | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PSEN2 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 84/328 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPRN | c.1897C>A p.R633S | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRN | c.185G>T p.C62F | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTPRQ | c.2888C>T p.A963V (on ENST00000616559; = p.A921V on NM_001145026.2) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RICTOR | c.994T>A p.Y332N | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SAMD9L | c.1516A>G p.S506G | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCAI | c.410A>T p.Y137F (on ENST00000336505 / NM_001144877.3; = p.Y160F on NM_173690.5) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SRCIN1 | c.1081C>T p.R361C (on ENST00000621492; = p.R327C on NM_025248.3) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SUSD3 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SYNDIG1 | c.528G>A p.M176I | Missense Mutation (SNP) | VAF 172/427 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- TCP10L2 | c.539C>A p.T180K | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- TNK1 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 117/225 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- TNS1 | c.2869G>T p.E957* | Nonsense Mutation (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- TRGV9 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 79/177 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TSHZ2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 64/480 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UGT2B4 | c.461T>C p.F154S | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC5C | c.444C>A p.S148R | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- UPF3A | c.1371G>C p.R457S | Missense Mutation (SNP) | VAF 199/437 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP35 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2
- ZFP1 | c.1061G>A p.C354Y | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF350 | c.920T>G p.V307G | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2
- ZNF469 | c.2380G>A p.A794T | Missense Mutation (SNP) | VAF 116/574 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF565 | c.1567G>C p.A523P (on ENST00000355114; = p.A483P on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ZNF607 | c.1950_1951del p.C650Wfs*5 | Frame Shift Del (DEL) | VAF 32/168 reads (19%) | called by pindel, varscan2
- ZSWIM3 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 218/396 reads (55%) | called by muse, mutect2, varscan2
- ACTA1 | c.1005G>A p.P335= | Silent (SNP) | VAF 98/360 reads (27%) | catalogued as rs763219295, COSV100796760; called by muse, mutect2, varscan2
- AGGF1 | c.327G>A p.Q109= | Silent (SNP) | VAF 51/105 reads (49%) | called by muse, mutect2, varscan2
- APOB | c.2019G>T p.L673= | Silent (SNP) | VAF 92/316 reads (29%) | called by mutect2, varscan2
- ASNSD1 | c.1927T>C p.L643= | Silent (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- BACH2 | c.1446C>T p.H482= | Silent (SNP) | VAF 67/226 reads (30%) | catalogued as rs147210309; called by muse, mutect2, varscan2
- BRCA2 | c.7602G>A p.A2534= | Silent (SNP) | VAF 75/323 reads (23%) | catalogued as rs81002826; ClinVar: likely benign; called by muse, mutect2, varscan2
- CA6 | c.144G>A p.S48= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as rs371134339; called by muse, mutect2, varscan2
- CIT | c.436C>A p.R146= | Silent (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- CSMD2 | c.2427C>T p.R809= | Silent (SNP) | VAF 47/195 reads (24%) | catalogued as rs764477631, COSV53916959; called by muse, mutect2, varscan2
- CTU1 | c.672C>T p.Y224= | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as rs368793980, COSV70292323; called by muse, mutect2, varscan2
- CYP51A1 | c.1398G>A p.K466= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs769919197; called by muse, mutect2, varscan2
- DAB1 | c.693T>G p.V231= | Silent (SNP) | VAF 51/227 reads (22%) | called by muse, mutect2, varscan2
- DIP2A | c.3135G>A p.V1045= | Silent (SNP) | VAF 137/245 reads (56%) | called by muse, mutect2, varscan2
- DMXL2 | c.4089G>A p.R1363= | Silent (SNP) | VAF 19/238 reads (8%) | catalogued as rs1238535679; called by muse, mutect2
- FBXL13 | c.1779G>T p.L593= | Silent (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- GHR | c.483C>T p.N161= | Silent (SNP) | VAF 26/392 reads (7%) | catalogued as rs576823676; called by muse, mutect2
- HMCN1 | c.11487G>T p.G3829= | Silent (SNP) | VAF 94/387 reads (24%) | called by muse, mutect2, varscan2
- HTRA3 | c.1122C>T p.A374= | Silent (SNP) | VAF 68/294 reads (23%) | called by muse, mutect2, varscan2
- HYDIN | c.5202C>T p.F1734= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs746347447, COSV59269993, COSV59271353; called by mutect2, varscan2
- ITSN1 | c.582A>G p.L194= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs1447961077; called by muse, mutect2, varscan2
- KCNJ16 | c.42C>T p.D14= | Silent (SNP) | VAF 22/278 reads (8%) | catalogued as rs148762846, COSV52253062; called by muse, mutect2
- LETM2 | c.1332G>T p.P444= (on ENST00000379957 / NM_001286819.2; = p.P349= on NM_144652.3) | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99907392; called by muse, mutect2, varscan2
- MRPS2 | c.240C>T p.S80= | Silent (SNP) | VAF 78/150 reads (52%) | catalogued as rs370940557, COSV54092216; called by muse, mutect2, varscan2
- MUC2 | c.2460C>T p.S820= | Silent (SNP) | VAF 63/255 reads (25%) | catalogued as rs376792696; called by muse, mutect2, varscan2
- NRN1 | c.366C>A p.L122= | Silent (SNP) | VAF 42/379 reads (11%) | called by muse, mutect2, varscan2
- OLFML1 | c.906G>T p.L302= | Silent (SNP) | VAF 21/502 reads (4%) | catalogued as COSV100206746; called by muse, mutect2
- OR2B3 | c.192T>C p.T64= | Silent (SNP) | VAF 129/283 reads (46%) | called by muse, mutect2, varscan2
- OR2G6 | c.726G>A p.S242= | Silent (SNP) | VAF 87/327 reads (27%) | catalogued as rs552819557, COSV58573606, COSV58575678; called by muse, mutect2, varscan2
- OR51M1 | c.285G>T p.G95= | Silent (SNP) | VAF 130/578 reads (22%) | called by muse, mutect2, varscan2
- SCN1A | c.1764C>T p.N588= | Silent (SNP) | VAF 31/227 reads (14%) | catalogued as rs1026954517, COSV100322735; called by muse, mutect2, varscan2
- TLL1 | c.1725A>G p.E575= | Silent (SNP) | VAF 32/310 reads (10%) | called by muse, mutect2, varscan2
- TNRC18 | c.7587C>A p.P2529= | Silent (SNP) | VAF 104/436 reads (24%) | called by muse, mutect2, varscan2
- TSHZ3 | c.810C>T p.D270= | Silent (SNP) | VAF 48/204 reads (24%) | catalogued as rs775613015, COSV53666834; called by muse, mutect2, varscan2
- ZNF276 | c.924C>T p.A308= (on ENST00000443381 / NM_001113525.2; = p.A233= on NM_152287.4) | Silent (SNP) | VAF 343/818 reads (42%) | called by muse, mutect2, varscan2
- ABI3BP | c.1576+16735G>A | Intron (SNP) | VAF 28/138 reads (20%) | catalogued as rs1054539647; called by muse, mutect2, varscan2
- AL133467.5 | chr14:95665051 G>A | 3'Flank (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- ARFGAP1 | c.834+318G>A | Intron (SNP) | VAF 66/418 reads (16%) | catalogued as rs1036131414; called by muse, mutect2, varscan2
- CHFR | c.1266-18C>T | Intron (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- CLCNKB | c.*11C>A | 3'UTR (SNP) | VAF 38/156 reads (24%) | called by muse, varscan2
- COL18A1 | c.3928+759G>A | Intron (SNP) | VAF 170/480 reads (35%) | catalogued as rs1470311733; called by mutect2, varscan2
- CREBBP | c.4395-21G>A | Intron (SNP) | VAF 124/302 reads (41%) | catalogued as rs369347758; called by mutect2, varscan2
- EZR | c.13-95G>A | Intron (SNP) | VAF 115/379 reads (30%) | catalogued as rs374768176; called by mutect2, varscan2
- ING5 | c.483-3396G>A | Intron (SNP) | VAF 47/189 reads (25%) | catalogued as rs757340133; called by muse, mutect2, varscan2
- KIF16B | c.3498+3117C>T | Intron (SNP) | VAF 139/374 reads (37%) | catalogued as rs1255286974, COSV100733817; called by muse, mutect2, varscan2
- KIR3DX1 | n.815C>T | RNA (SNP) | VAF 110/412 reads (27%) | called by muse, mutect2, varscan2
- LDHA | c.*253G>A | 3'UTR (SNP) | VAF 33/298 reads (11%) | catalogued as rs758268446; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LINC01387 | n.174G>A | RNA (SNP) | VAF 45/142 reads (32%) | catalogued as rs1015365867; called by muse, mutect2, varscan2
- OSBPL8 | c.1533+48G>T | Intron (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- PGM1 | c.-39C>T | 5'UTR (SNP) | VAF 121/305 reads (40%) | called by muse, mutect2, varscan2
- RFNG | c.828+89G>A | Intron (SNP) | VAF 53/187 reads (28%) | catalogued as rs569315188; called by muse, mutect2, varscan2
- SEC61B | c.-17C>A | 5'UTR (SNP) | VAF 89/200 reads (45%) | called by muse, mutect2, varscan2
- SMG1P6 | n.2427G>A | RNA (SNP) | VAF 9/72 reads (13%) | catalogued as rs3204947; called by muse, mutect2, varscan2
- SMG1P6 | n.2426T>C | RNA (SNP) | VAF 9/73 reads (12%) | catalogued as rs3204946; called by muse, mutect2, varscan2
- STK25 | c.261+44G>T | Intron (SNP) | VAF 93/397 reads (23%) | catalogued as rs370702495; called by muse, mutect2, varscan2
- TTC4 | c.111+37C>A | Intron (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
